Somatic mutation profile of tumor specimen TARGET-20-PARNNT-09A (aliquot TARGET-20-PARNNT-09A-01D) from TARGET case TARGET-20-PARNNT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.0 years (5,840 days).
Specimen TARGET-20-PARNNT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28e19d6c-306a-489d-9e44-09efd19a93cf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNNT-14A (Bone Marrow Normal), aliquot TARGET-20-PARNNT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1eee4b-0702-4f67-aa15-9b0375a63882

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MACF1 | c.12196C>T p.R4066C (on ENST00000372915; = p.R1999C on NM_012090.5) | Missense Mutation (SNP) | VAF 105/244 reads (43%) | catalogued as rs201462187, COSV57107007, COSV57124998; called by muse, mutect2, varscan2
- MYH4 | c.3877C>T p.R1293* | Nonsense Mutation (SNP) | VAF 111/236 reads (47%) | catalogued as rs763090716, COSV55112576; called by muse, mutect2, varscan2
